Somatic mutation profile of tumor specimen TCGA-EB-A3XE-01A (aliquot TCGA-EB-A3XE-01A-12D-A23B-08) from TCGA case TCGA-EB-A3XE, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 77.1 years (28,148 days).
Specimen TCGA-EB-A3XE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66c68f47-de10-4407-861e-d0d3f928f965.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A3XE-10A (Blood Derived Normal), aliquot TCGA-EB-A3XE-10A-01D-A23B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/550d99fe-bfdf-421f-8149-de4f093a2b46

The open-access MAF lists 18 somatic variants for this specimen: 17 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 16, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DAB1 | c.290T>C p.F97S | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as COSV59723124; called by muse, mutect2
- DSCAM | c.5965C>A p.Q1989K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV68022316; called by muse, mutect2, varscan2
- GABRB2 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV50904309; called by muse, mutect2, varscan2
- HDAC7 | c.2842G>A p.E948K (on ENST00000427332; = p.E987K on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV50323838, COSV99316553; called by muse, mutect2
- LRRC43 | c.677C>A p.S226Y | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60288382, COSV60289578; called by muse, mutect2, varscan2
- MGME1 | c.53T>G p.F18C | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV66623972; called by muse, mutect2, varscan2
- MMD2 | c.74A>G p.H25R | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV68659928; called by muse, mutect2, varscan2
- NEB | c.5418G>T p.K1806N | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.697); catalogued as COSV50835969, COSV51437587; called by muse, mutect2, varscan2
- PDK4 | c.998G>C p.G333A | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV50010373, COSV99138710; called by muse, mutect2, varscan2
- PFKM | c.1723G>A p.G575S | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs779275589, COSV56656315; called by muse, mutect2, varscan2
- PRB2 | c.623G>A p.G208E | Missense Mutation (SNP) | VAF 74/335 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs780328133, COSV66982404; called by muse, varscan2
- SPDL1 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs753781869, COSV54667308; called by muse, mutect2, varscan2
- STIL | c.1883C>T p.S628F | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.79); catalogued as COSV54547765; called by muse, mutect2, varscan2
- TRIP11 | c.1565A>T p.Q522L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV50914145; called by muse, mutect2, varscan2
- WDR49 | c.1396A>G p.T466A (on ENST00000308378 / NM_001366158.1; = p.T807A on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV57703985; called by muse, mutect2, varscan2
- SPATC1 | c.1321del p.A441Pfs*45 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel, varscan2
- DCAF1 | c.3321C>T p.F1107= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV60041150; called by muse, mutect2, varscan2
